Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SM-01A (Primary Tumor).

[page 1 of 8]
Result Type: Surgical Pathology Report

Result Date:

Performed By:

**Encounter
info:**

ICD O-3

Carcinoma, papillary renal cell
826013

Site @ Kidney NOS
C64.9

Surgical Pathology Report

Final

JW 10/4/13

Surgical Pathology Report
REVISED REPORT

DIAGNOSIS:
AMENDED REPORT

Report is amended to correct formatting issues. The diagnosis remains unchanged.

CASE AMENDED: to report the final diagnosis on parts A and B after outside consultation.

A. Left renal vein, thrombectomy:

Papillary renal cell carcinoma.

B. Left kidney and para-aortic lymph nodes:

Papillary renal cell carcinoma (4.2 cm), type 2, invading into wall of renal vein and into perinephric/periadrenal adipose tissue.

Pn TSS, chn cell < 5%.
BCR

Margins, free of tumor.

Metastatic carcinoma to multiple hilar lymph nodes.

Renal synoptic report:

Procedure/laterality: Left radical nephrectomy and para-aortic lymphadenectomy.

Histologic type: Papillary renal cell carcinoma, type 2.

Nuclear grade (Fuhrman, 1-4): 4.

Tumor size: 4.2 x 3.5 x 3.5 cm.

Tumor site: Lower pole.

Tumor focality: Unifocal.

Sarcomatoid features: Present (5-10%).

Tumor necrosis: Present (10% of tumor).

Macroscopic extent of tumor: Tumor involves renal vein and perinephric (including periadrenal) adipose tissue.

Microscopic tumor extension: Tumor involves wall of renal vein and invades perinephric and periadrenal adipose tissue.

Surgical margins: Free of tumor.

Lymphovascular invasion: Present.

Lymph nodes: Metastatic carcinoma to multiple (matted) hilar lymph nodes. No extranodal extension identified.

Pathologic findings in nonneoplastic kidney: Changes compatible with embolization.

Pathologic staging (AJCC 2010): pT3a, pN1.

Biorepository sample: Tumor present (100% of all tumor samples)

[page 2 of 8]
taken).

Blocks containing malignancy suitable for additional testing:

B4, B5 and B11.

C. Left common iliac lymph nodes, excision:

Metastatic carcinoma to one lymph node (1/1).

No extranodal extension identified.

D. Descending colon and sigmoid, segmental resection:

Segment of colon with serosal fibrovascular adhesions.

Negative for malignancy.

E. Suprarenal para-aortic lymph nodes, excision:

Metastatic carcinoma to one of one lymph node (1/1).

No extranodal extension identified.

F. Inter-aortic lymph node, excision:

Metastatic carcinoma to multiple matted lymph nodes.

No extranodal extension identified.

G. Left common iliac lymph node #2, excision:

Metastatic carcinoma to one lymph node (1/1).

No extranodal extension identified.

DIAGNOSIS COMMENT:

This supplemental report is being issued to provide the final diagnosis for parts A and B after consultation with and after performing a FISH study to rule out Xp11.2 translocation-associated renal cell carcinoma.

The tumor exhibits a predominant papillary architecture, lined by cells with a variably eosinophilic to clear cytoplasm. Areas with solid pattern of growth, also with clear cell features, are present. Scattered calcifications are seen. Within the solid areas, some tumor cells exhibit spindling and atypia, compatible with focal sarcomatoid de-differentiation. Immunohistochemical stains for the tumor cells are positive for cytokeratin 7, EMA (focal), racemase (p504s), vimentin and PAX-8 (focal). A stain for p63 is negative. The overall cytoarchitectural features and immunohistochemical profile are compatible with a papillary renal cell carcinoma, type 2. Although focal areas are suggestive of Xp11 translocation carcinoma, the immunohistochemical profile (positivity for EMA and cytokeratin 7) do not support this impression, and FISH for the detection of rearrangement of the TFE3 gene locus at chromosome Xp11.2 is negative. Please see their report for full details.

Report electronically signed by
Transcribed by:

AMENDMENTS: (Previous Signout Date:
Revision Description:
See final report for amendment reason.

....Previous Diagnosis....

CASE AMENDED: to report the final diagnosis on parts A and B after outside consultation.

A. Left renal vein, thrombectomy: Papillary renal cell carcinoma.

B. Left kidney and para-aortic lymph nodes:

Procedure/laterality: Left radical nephrectomy and para-aortic lymphadenectomy.

Histologic type: Papillary renal cell carcinoma, type 2.

[page 3 of 8]
Nuclear grade (Fuhrman,
1-4): 4.
Tumor size: 4.2 x 3.5 x 3.5 cm.
Tumor site: Lower pole.
Tumor focality: Unifocal.
Sarcomatoid
features: Present (5-10%).
Tumor necrosis: Present (10% of tumor).
Macroscopic extent of tumor: Tumor
involves renal vein and perinephric (including periadrenal) adipose
tissue. Microscopic tumor extension: Tumor involves wall
of renal vein and invades perinephric and periadrenal adipose
tissue.
Surgical margins: Free of tumor.
Lymphovascular invasion:
Present.
Lymph nodes: Metastatic carcinoma to multiple hilar lymph nodes. No
extranodal extension identified. Pathologic findings
in nonneoplastic kidney: Changes compatible with embolization.
Pathologic staging (AJCC 2010): pT3a, pN1.
Biorepository sample:
Tumor present (100% of all tumor samples taken).
Blocks containing malignancy suitable for additional
testing: B4, B5 and B11. C. Left common
iliac lymph nodes, excision:
Metastatic carcinoma to one lymph node (1/1). No
extranodal extension identified. D. Descending
colon and sigmoid, segmental resection:
Segment of colon with serosal fibrovascular
adhesions. Negative for malignancy. E.
Suprarenal para-aortic lymph nodes, excision:
Metastatic carcinoma to one of one lymph
node (1/1). F. Inter-aortic
lymph node, excision:
Metastatic carcinoma to multiple matted lymph nodes. No
extranodal extension identified. G. Left common iliac
lymph node #2, excision:
Metastatic carcinoma to one lymph node (1/1). No
extranodal extension identified.
....Previous Diagnosis Comment....
This supplemental report is being issued to provide the final
diagnosis for parts A and B after consultation with
and after performing a FISH study to rule out Xp11.2
translocation-associated renal cell carcinoma.

The tumor exhibits a predominant papillary architecture, lined by
cells with a variably eosinophilic to clear cytoplasm. Areas with
solid pattern of growth, also with clear cell features, are present.
Scattered calcifications are seen. Within the solid areas, some
tumor cells exhibit spindling and atypia, compatible with focal
sarcomatoid de-differentiation. Immunohistochemical stains for the
tumor cells are positive for cytokeratin 7, EMA (focal), racemase
(p504s), vimentin and PAX-8 (focal). A stain for p63 is negative.
The overall cytoarchitectural features and immunohistochemical
profile are compatible with a papillary renal cell carcinoma, type
2. Although focal areas are suggestive of Xp11 translocation
carcinoma, the immunohistochemical profile (positivity for EMA and
cytokeratin 7) do not support this impression, and FISH for the
detection of rearrangement of the TFE3 gene locus at chromosome
Xp11.2 is negative. Please see their report for full

[page 4 of 8]
details.

AMENDMENTS: (Previous Signout Date:

Revision Description:

Please see Final Report for amendment reason

....Original Diagnosis....

A. Left renal vein, thrombectomy:

Renal cell carcinoma, subtype pending consultation.

B. Left kidney and para-aortic lymph nodes:

Procedure/laterality: Left radical nephrectomy and para-aortic lymphadenectomy.

Histologic type: Renal cell carcinoma, subtype pending consultation. (See Comment) Nuclear grade (Fuhrman, 1-4):

3.

Tumor size: 4.2 x 3.5 x 3.5 cm.

Tumor site: Lower pole.

Tumor focality: Unifocal.

Sarcomatoid features: Not identified.

Tumor necrosis: Present (10% of tumor).

Macroscopic extent of tumor: Tumor involves renal vein and perinephric (including periadrenal) adipose tissue.

Microscopic tumor extension: Tumor involves wall of renal vein and invades perinephric and periadrenal adipose tissue.

Surgical margins: Free of tumor.

Lymphovascular invasion: Present.

Lymph nodes: Metastatic carcinoma to multiple hilar lymph nodes. No extranodal extension identified.

Pathologic findings in nonneoplastic kidney: Changes compatible with embolization.

Pathologic staging (AJCC 2010): pT3a, pN1.

Biorepository sample: Tumor present (100% of all tumor samples taken).

Blocks containing malignancy suitable for additional testing: B4, B5 and B11.

C. Left common iliac lymph nodes, excision:

Metastatic carcinoma to one lymph node (1/1).

No extranodal extension identified.

D. Descending colon and sigmoid, segmental resection:

Segment of colon with serosal fibrovascular adhesions.

Negative for malignancy.

E. Suprarenal para-aortic lymph nodes, excision:

Metastatic carcinoma to one of one lymph node (1/1).

F. Inter-aortic lymph node, excision:

Metastatic carcinoma to multiple matted lymph nodes.

No extranodal extension identified.

G. Left common iliac lymph node #2, excision:

Metastatic carcinoma to one lymph node (1/1).

No extranodal extension identified.

....Original Diagnosis Comment....

The morphologic features of the tumor are unusual. The tumor exhibits a predominant papillary architecture, lined by cells with a

[page 5 of 8]
variably eosinophilic to clear cytoplasm. Areas with solid pattern of growth, also with clear cell features, are present. Scattered calcifications are seen. Within the solid areas, some tumor cells exhibit spindling and atypia; however, no definitive sarcomatoid de-differentiation is identified.

Immunohistochemical stains for the tumor cells are positive for cytokeratin 7, EMA (focal), racemase (p504s), vimentin and PAX-8 (focal). A stain for p63 is negative.

The overall cytoarchitectural features and immunohistochemical profile are compatible with a renal cell carcinoma; subtyping of the tumor is difficult. The tumor predominantly exhibits features of a papillary renal cell carcinoma (type 2). Although focal areas are suggestive of Xp11 translocation carcinoma, the immunohistochemical profile (positivity for EMA and cytokeratin 7) do not support this impression. This case will be sent to _____ for expert consultation. Their findings and final diagnosis will be reported in a supplemental report.

....Original Gross Description....

A. Received fresh labeled and "tumor thrombus left renal vein," are two portions of soft gray-tan somewhat friable tissue, 1.5 cm and 1.8 cm. Sampled in one cassette labeled

B. Received fresh labeled and "left kidney and periaortic nodes" is a radical nephrectomy specimen, 1050 g including the surrounding perinephric fat and attached periaortic lymph node tissue. The kidney without attached fat is 295 g and 12.5 x 8 x 6.5 cm. The attached ureter is 10 x 1 cm. The kidney has a circumscribed exophytic mass in the lower pole that is 4.2 x 3.5 x 3.5 cm. The mass grossly appears to extend into the adjacent perinephric fat. There is not definitive gross extension beyond Gerota's fascia. The tumor does not definitively extend into the renal sinus fat. The hilar vasculature and intrarenal vessels are thrombosed. The renal vein also contains thrombus and is somewhat suggestive of tumor thrombus. The leading edge of the thrombus within the renal vein is rounded and the margin is not grossly involved by tumor. Within the hilar soft tissue and adjacent s tissue is a matted mass of tumor-replaced lymph nodes. This is up to 14 x 5.5 x 5 cm. Additional tumor nodules are identified within the perinephric fat and immediately adjacent to the attached adrenal gland. The renal pelvis is hyperemic and slightly granular; however, there is no grossly evident mass. Sampled in nineteen cassettes labeled

B1) Ureter and vascular margin, B2-B5) renal tumor samples; B6) longitudinal section of renal vein with apparent tumor thrombus; B7) additional hilar vasculature with thrombus; B8) perinephric fat nodule; B9-B11) periaortic/hilar lymph node samples; B12) renal pelvis; B13-B14) adrenal gland with apparent tumor nodules and surrounding fat; B15) grossly nonneoplastic kidney; B16) mirror image of biorepository sample, kidney tumor (sample 1 not inked, sample 2 inked); B17) mirror image of biorepository samples, lymph node metastasis (three separate samples, differentiated with no ink, blue ink, and black ink; B18) mirror image of biorepository sample, grossly nonneoplastic kidney; B19) additional samples of ureter. Samples of tissue are submitted

[page 6 of 8]
for

C. Received fresh labeled and "left common iliac lymph node" is a nodular flesh tan-gray portion of tissue, 4.5 x 2.5 x 2.5 cm. Sampled in two cassettes labeled

D. Received fresh labeled and "descending colon and sigmoid" is a segment of large bowel, 43 cm in length and up to 4 cm in external diameter. The serosal surfaces are predominately glistening and smooth with focal areas of possible adhesions. The mucosa intact. There is no mucosal or pericolic mass identified. Sampled in three cassettes labeled . D1) Sample adjacent to each surgical end; D2-D3) additional sections.

E. Received fresh labeled and "suprarenal periaortic lymph nodes" are two apparent lymph nodes, 1.8 cm and 2.5 cm in maximum dimension. A sample of each is submitted in one cassette labeled

F. Received fresh labeled " and "inter aortic lymph nodes" is a matted mass of apparent lymph nodes replaced by tumor, 7.5 x 4 x 2.5 cm. Sampled in three cassettes labeled

G. Received fresh labeled "" and "left common iliac lymph node number 2" are two irregular portions of apparent tumor-replaced lymph node tissue, 2.5 x 1.5 1.2 cm, and 3.5 x 2 x 1.5 cm. Sampled in two cassettes labeled

CLINICAL INFORMATION:

Renal mass.

SPECIMEN(S):

A:Left renal vein thrombus tumor
B:Left kidney and para aortic lymph nodes
C:Left common iliac lymph nodes
D:Descending colon and sigmoid
E:Supra renal para aortic lymph nodes
F:Inter aortic lymph nodes
G:Left common iliac lymph nodes

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled " and "tumor thrombus left renal vein," are two portions of soft gray-tan somewhat friable tissue, 1.5 cm and 1.8 cm. Sampled in one cassette labeled

B. Received fresh labeled and "left kidney and periaortic nodes" is a radical nephrectomy specimen, 1050 g including the surrounding perinephric fat and attached periaortic lymph node tissue. The kidney without attached fat is 295 g and 12.5 x 8 x 6.5 cm. The attached ureter is 10 x 1 cm. The kidney has a

[page 7 of 8]
circumscribed exophytic mass in the lower pole that is 4.2 x 3.5 x 3.5 cm. The mass grossly appears to extend into the adjacent perinephric fat. There is not definitive gross extension beyond Gerota's fascia. The tumor does not definitively extend into the renal sinus fat. The hilar vasculature and intrarenal vessels are thrombosed. The renal vein also contains thrombus and is somewhat suggestive of tumor thrombus. The leading edge of the thrombus within the renal vein is rounded and the margin is not grossly involved by tumor. Within the hilar soft tissue and adjacent s tissue is a matted mass of tumor-replaced lymph nodes. This is up to 14 x 5.5 x 5 cm. Additional tumor nodules are identified within the perinephric fat and immediately adjacent to the attached adrenal gland. The renal pelvis is hyperemic and slightly granular; however, there is no grossly evident mass. Sampled in nineteen cassettes labeled . B1) Ureter and vascular margin, B2-B5) renal tumor samples; B6) longitudinal section of renal vein with apparent tumor thrombus; B7) additional hilar vasculature with thrombus; B8) perinephric fat nodule; B9-B11) periaortic/hilar lymph node samples; B12) renal pelvis; B13-B14) adrenal gland with apparent tumor nodules and surrounding fat; B15) grossly nonneoplastic kidney; B16) mirror image of biorepository sample, kidney tumor (sample 1 not inked, sample 2 inked); B17) mirror image of biorepository samples, lymph node metastasis (three separate samples, differentiated with no ink, blue ink, and black ink; B18) mirror image of biorepository sample, grossly nonneoplastic kidney; B19) additional samples of ureter. Samples of tissue are submitted for

C. Received fresh labeled and "left common iliac lymph node" is a nodular flesh tan-gray portion of tissue, 4.5 x 2.5 x 2.5 cm. Sampled in two cassettes labeled

D. Received fresh labeled and "descending colon and sigmoid" is a segment of large bowel, 43 cm in length and up to 4 cm in external diameter. The serosal surfaces are predominately glistening and smooth with focal areas of possible adhesions. The mucosa intact. There is no mucosal or pericolic mass identified. Sampled in three cassettes labeled . D1) Sample adjacent to each surgical end; D2-D3) additional sections.

E. Received fresh labeled and "suprarenal periaortic lymph nodes" are two apparent lymph nodes, 1.8 cm and 2.5 cm in maximum dimension. A sample of each is submitted in one cassette labeled

F. Received fresh labeled and "inter aortic lymph nodes" is a matted mass of apparent lymph nodes replaced by tumor, 7.5 x 4 x 2.5 cm. Sampled in three cassettes labeled

G. Received fresh labeled and "left common iliac lymph node number 2" are two irregular portions of apparent tumor-replaced lymph node tissue, 2.5 x 1.5 1.2 cm, and 3.5 x 2 x 1.5 cm. Sampled in two cassettes labeled

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA).

[page 8 of 8]
The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file b3a06edc-8c73-4692-b334-64c41b7088ad (TCGA-SX-A7SM.C5923DD8-8DF2-460B-9774-629161D1DA20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).